Somatic mutation profile of tumor specimen HCM-CSHL-0434-C24-01A (aliquot HCM-CSHL-0434-C24-01A-11D-A78U-36) from HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 248bca87-4ca4-4213-9139-eb009d426c31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0434-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0434-C24-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efdffbb1-2d41-4f32-a54d-789f0fa1ed6e

The open-access MAF lists 70 somatic variants for this specimen: 39 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 20, Intron 4, Nonsense Mutation 2, Splice Site 2, RNA 2, 5'UTR 2, 5'Flank 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 43/304 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 109/580 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASCC3 | c.4729G>A p.A1577T | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs187359221; called by muse, mutect2
- CFL1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV57380536; called by muse, mutect2, varscan2
- DNAH7 | c.8779C>T p.Q2927* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs374570869; called by muse, mutect2, varscan2
- DUSP7 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs879043778; called by muse, mutect2, varscan2
- ESX1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs782576955; called by muse, mutect2, varscan2
- FAM71E2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs775529719, COSV52772730; called by mutect2, varscan2
- FARP2 | c.288+2T>C p.X96_splice | Splice Site (SNP) | VAF 15/129 reads (12%) | catalogued as rs1166151853; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- GMCL2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1368534206; called by muse, mutect2
- GRIA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs531706550, COSV53596718; called by muse, mutect2, varscan2
- KLHL42 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 60/434 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as rs374664683; called by muse, mutect2, varscan2
- LRRTM4 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1479336871, COSV69140756; called by muse, mutect2
- LTBP1 | c.2878G>T p.E960* (on ENST00000404816 / NM_206943.4; = p.E634* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 37/178 reads (21%) | catalogued as COSV100617209, COSV63195429; called by muse, mutect2, varscan2
- MAGEB4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs770408937, COSV66775187; called by muse, mutect2, varscan2
- MPDZ | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs779501527; called by muse, mutect2, varscan2
- NPAP1 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1310332702; called by muse, mutect2
- PAQR4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748058094, COSV51893053; called by muse, mutect2
- PLXNA2 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs778037020; called by muse, mutect2, varscan2
- SIPA1L2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs368264412; called by muse, mutect2
- SKOR1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58244084; called by muse, mutect2, varscan2
- SLC24A3 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as COSV100043446; called by muse, mutect2, varscan2
- TMPRSS6 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1270960721, COSV60976662; called by muse, mutect2
- TUB | c.124C>T p.R42C (on ENST00000299506 / NM_177972.3; = p.R97C on NM_003320.4) | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs772509519; called by muse, mutect2, varscan2
- TUBA3C | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs372020555, COSV67139306; called by muse, mutect2, varscan2
- VPS13D | c.8530G>T p.D2844Y | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1425394183; called by muse, mutect2, varscan2
- ZBED9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as rs185476387, COSV71729796; called by muse, mutect2, varscan2
- ARID3C | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DACT1 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GON4L | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF1 | c.2938G>C p.V980L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NFE2L1 | c.1080T>A p.N360K | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2
- NRAP | c.3233G>A p.G1078D (on ENST00000359988 / NM_001322945.2; = p.G1043D on NM_006175.4) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2
- PRPF6 | c.2029-1G>A p.X677_splice | Splice Site (SNP) | VAF 126/408 reads (31%) | called by muse, mutect2, varscan2
- SYNE1 | c.5320C>A p.L1774M (on ENST00000367255 / NM_182961.4; = p.L1781M on NM_033071.3) | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- UBR5 | c.5366G>A p.S1789N | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- WFDC1 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2
- ZNF26 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- A2M | c.66C>T p.D22= | Silent (SNP) | VAF 26/285 reads (9%) | catalogued as rs1397674410; called by muse, mutect2
- AJAP1 | c.717C>T p.S239= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs377710853; called by mutect2, varscan2
- ARMC4 | c.1668C>T p.A556= | Silent (SNP) | VAF 60/396 reads (15%) | catalogued as rs761407359; called by muse, mutect2, varscan2
- COL20A1 | c.3009C>T p.P1003= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as rs771914301, COSV58911381; called by muse, mutect2, varscan2
- DLGAP2 | c.933G>A p.T311= | Silent (SNP) | VAF 50/310 reads (16%) | catalogued as rs746806848; called by muse, mutect2, varscan2
- FAM53C | c.222G>C p.L74= | Silent (SNP) | VAF 26/121 reads (21%) | called by mutect2, varscan2
- FBXO28 | c.858C>T p.R286= | Silent (SNP) | VAF 39/304 reads (13%) | called by muse, mutect2, varscan2
- HAMP | c.210C>T p.C70= | Silent (SNP) | VAF 108/1450 reads (7%) | catalogued as rs760104316, COSV55885844; called by muse, mutect2
- HOXB3 | c.127C>T p.L43= | Silent (SNP) | VAF 69/291 reads (24%) | called by muse, mutect2, varscan2
- HSPG2 | c.7662C>T p.N2554= | Silent (SNP) | VAF 74/378 reads (20%) | called by muse, mutect2, varscan2
- MYO16 | c.4461G>A p.P1487= | Silent (SNP) | VAF 13/171 reads (8%) | catalogued as rs1282083679; called by muse, mutect2
- NRG1 | c.1593C>T p.Y531= (on ENST00000405005 / NM_013964.5; = p.Y536= on NM_013956.5) | Silent (SNP) | VAF 36/325 reads (11%) | catalogued as rs576124928, COSV55153115; called by muse, mutect2, varscan2
- OCA2 | c.1221C>T p.F407= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as rs370349105; called by muse, mutect2, varscan2
- OR5C1 | c.732C>T p.T244= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs532966704, COSV101030530; called by muse, mutect2, varscan2
- ORAI2 | c.489C>T p.A163= | Silent (SNP) | VAF 69/437 reads (16%) | catalogued as rs769632596; called by muse, mutect2, varscan2
- SH2D4B | c.483C>T p.H161= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as rs1353105917; called by muse, mutect2
- SLC26A4 | c.474C>T p.D158= | Silent (SNP) | VAF 102/375 reads (27%) | catalogued as COSV55915305; called by muse, mutect2, varscan2
- SLC9A9 | c.1404C>T p.L468= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs576013614, COSV100339003, COSV57235318; called by muse, mutect2
- TP73 | c.1863C>T p.A621= | Silent (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- ZNF862 | c.58T>C p.L20= | Silent (SNP) | VAF 39/160 reads (24%) | called by muse, mutect2, varscan2
- C16orf87 | c.-3A>G | 5'UTR (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29699652 T>C | 3'Flank (SNP) | VAF 75/507 reads (15%) | called by muse, mutect2, varscan2
- LINC01164 | n.674_675del | RNA (DEL) | VAF 29/184 reads (16%) | catalogued as rs759232943; called by mutect2, varscan2*
- MCF2L2 | c.77-10749del | Intron (DEL) | VAF 19/113 reads (17%) | called by mutect2, pindel, varscan2
- MTHFD2L | chr4:74157926 T>C | 5'Flank (SNP) | VAF 47/240 reads (20%) | catalogued as rs1299716458; called by muse, mutect2, varscan2
- REPIN1 | c.-92C>G | 5'UTR (SNP) | VAF 51/295 reads (17%) | catalogued as rs1367020694; called by muse, mutect2, varscan2
- SCOC-AS1 | n.6637C>T | RNA (SNP) | VAF 23/258 reads (9%) | catalogued as rs940726834; called by muse, mutect2
- SLC26A3 | c.1677+28dup | Intron (INS) | VAF 90/328 reads (27%) | catalogued as rs771040356; called by mutect2, pindel*, varscan2
- SLC39A9 | c.*3077C>T | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- TGFBI | c.459+22C>T | Intron (SNP) | VAF 9/71 reads (13%) | catalogued as rs749930646; called by muse, mutect2
- ZEB1 | c.58+43931G>A | Intron (SNP) | VAF 57/428 reads (13%) | catalogued as rs3895218; called by muse, mutect2, varscan2
